Gene-level copy-number profile of tumor specimen MP2PRT-PAVUHD-TMP1-A from MP2PRT case MP2PRT-PAVUHD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,540 days).
Specimen MP2PRT-PAVUHD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 875c433b-2294-4791-877a-96d2364e5d8a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVUHD-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/1bea5afa-1f96-4e0a-b536-fd0bc42554ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 1,923; copy number 2: 52,321; copy number 3: 4,028; copy number 4: 47; copy number 5: 30.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–3): TRDD1, TRDD2.
- chr14:105,881,034–106,012,420, 36 genes (within-gene range 0–1): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,514,410–31,577,923, 1 gene, copy number 5 (within-gene range 3–5): HM13.
- chr20:31,547,412–32,170,790, 29 genes, copy number 5: MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6.

Autosomal genes at a single copy (total copy number 1): 1,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
